Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48L, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48L-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

....

Clinical Diagnosis & History:

year old with right posterior medial high grade leiomyosarcoma.

Specimens Submitted:

1: CALF, RIGHT; EXCISION

DIAGNOSIS:

1. RIGHT CALF; EXCISION:

- HIGH GRADE LEIOMYOSARCOMA, INVOLVING ADIPOSE TISSUE AND SKELETAL MUSCLE.
- TUMOR SIZE: 6.3 x 4.2 x 3.7 CM.
- TUMOR IS PREDOMINANTLY VIABLE WITH ONLY FOCAL AREAS OF NECROSIS.
- TUMOR EXTENDS TO WITHIN 0.1 CM OF THE INKED DEEP AND LATERAL MARGINS.
- SKIN WITH SCAR AND SURGERY RELATED CHANGES.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically (Out) ***

Gross Description:

1) The specimen is received fresh labeled "right radical resection of right calf sarcoma, long stitch lateral, short stitch superior" and consists of an irregularly shaped excision of soft tissue measuring 13 x 7 x 4.2cm with overlying ellipse of unremarkable pink skin measuring 11 x 3 cm. The margins are inked (deep black, lateral blue, superior yellow, medial green, inferior red) and the specimen is sectioned to reveal a firm white tan well circumscribed mass measuring 6.3 x 4.2 x 3.7 cm at the deep aspect of the specimen abutting the deep, superior, and lateral inked margins. The remainder of the soft tissue is primarily fatty with a portion of skeletal muscle at the inferior aspect. The lesion is located 2.4 cm from the skin and contains a unilocular smooth walled cyst measuring 4 x 3 x 2 cm at the superficial aspect. Representative sections, TPS, and photos are submitted.

** Continued on next page **

1CD-03

leiomyosarcoma, NOS

8890/3

Site: calf, NOS

C49.2

9-11-12
RP

[page 2 of 2]
SURGICAL

Page 2 of 2

Summary of sections:

D-deep margin
S-superior margin
I-inferior margin
L-lateral margin
M-medial margin
SK-skin
T- tumor
C - cyst

Summary of Sections:

Part 1: CALF, RIGHT; EXCISION

Block	Sect.	Site	PCs
2		C	2
1		D	1
1		I	1
1		L	1
1		M	1
1		S	1
1		SK	1
4		T	4

** End of Report **

HPA Discrepancy		

428/20/12

Source: NCI Genomic Data Commons file a20a2fb4-0595-42fa-8cd4-fe75f421d43f (TCGA-DX-A48L.B2DFF591-42A2-4107-AD71-B988BF3BA9B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).